Somatic mutation profile of tumor specimen 0DNE0A from CCDI case PBBYDY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 1.5 years (535 days).
Specimen 0DNE0A: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59827027-6cb4-4e93-956d-a7ea03639948.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNE0P (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/024d7114-41f5-42f3-a137-4b7e90aa7ff4

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 2, Frame Shift Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DRAXIN | c.812G>A p.G271E | Missense Mutation (SNP) | VAF 145/1551 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as rs370101974; called by muse, mutect2
- GPR33 | c.364A>G p.I122V | Missense Mutation (SNP) | VAF 34/1276 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1296458675; called by muse, mutect2
- PLEC | c.1951C>T p.R651C (on ENST00000322810 / NM_201380.4; = p.R541C on NM_000445.5) | Missense Mutation (SNP) | VAF 32/815 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs370458177; ClinVar: uncertain significance; called by muse, mutect2
- HTR1E | c.651del p.S218Qfs*5 | Frame Shift Del (DEL) | VAF 452/1277 reads (35%) | called by mutect2, pindel, varscan2
- FRMD5 | c.1467C>T p.P489= | Silent (SNP) | VAF 88/715 reads (12%) | catalogued as rs755536011, COSV68726017; called by muse, mutect2, varscan2
- SPINK5 | c.474+99G>C | Intron (SNP) | VAF 156/348 reads (45%) | called by muse, mutect2, varscan2
- SPSB2 | c.664+73A>G | Intron (SNP) | VAF 93/202 reads (46%) | called by muse, mutect2, varscan2
